Gene-level copy-number profile of tumor specimen C3L-08265-03 from CPTAC case C3L-08265, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 61.0 years (22,274 days).
Specimen C3L-08265-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f3e02b96-7ab4-46f4-8f9d-5cdc18817c48.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-08265-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/bf310d2e-3ad9-4f02-a460-17dc1477da7d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 64; copy number 1: 10,742; copy number 2: 30,383; copy number 3: 13,704; copy number 4: 3,116; copy number 5: 195; copy number 6: 11; copy number 7: 186.

Homozygous deletions (total copy number 0; autosomes only): 64 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes (within-gene range 0–1): AC104164.2, MIR548BB.
- chr6:143,857,318–143,938,471, 1 gene (within-gene range 0–2): AL049844.3.
- chr6:143,864,436–143,938,343, 1 gene: ZC2HC1B.
- chr8:99,013,266–99,877,580, 13 genes (within-gene range 0–2): VPS13B, AC107909.2, AC107909.1, AP004290.1, AP004289.2, AP004289.1, Y_RNA, MIR599, MIR875, RN7SL350P, AC018442.1, AC018442.2, AC018442.3.
- chr9:60,914,407–62,711,398, 47 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2, RN7SL722P, FAM27C, AL391987.2, AL391987.1, AL391987.4, AL391987.3, Y_RNA, FAM242E, CR769775.1, AL590399.4, AL590399.3, AL590399.6, SNORA70, RN7SL544P, AL590399.1, FGF7P6, AL590399.5, AL590399.2, BX664725.1, LINC01189, FGF7P7, BX005266.2, BX005266.1, CNTNAP3P5, RBPJP7, RAB28P2, BX005266.3, ATP5F1AP7, SDR42E1P3, FKBP4P7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 392 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:109,603,254–110,491,277, 41 genes, copy number 5 (within-gene range 4–5): GNAT2, AMPD2, AL355310.2, RPL7P8, GSTM4, GSTM2, GSTM1, AC000032.1, GSTM5, AL158847.1, GSTM3, EPS8L3, NDUFA5P10, LINC01768, AL450468.1, AL450468.2, CSF1, AHCYL1, STRIP1, AL160006.1, ALX3, LINC01397, UBL4B, SLC6A17, SLC6A17-AS1, AL355990.1, LINC02586, KCNC4, AL137790.2, AL137790.1, RBM15-AS1, RBM15, LAMTOR5-AS1, SLC16A4, AL355488.1, LAMTOR5, PROK1, AL358215.1, AL358215.3, CYMP, CYMP-AS1.
- chr8:94,249,253–94,594,601, 10 genes, copy number 5: GEM, RPS4XP10, RAD54B, FSBP, VIRMA, AC023632.5, AC023632.2, AC023632.1, AC023632.3, AC023632.4.
- chr11:89,546,637–89,589,611, 1 gene, copy number 5 (within-gene range 4–5): AP003400.1.
- chr11:89,556,860–90,062,999, 40 genes, copy number 5: AP003400.3, AP003400.6, FOLH1B, UBTFL10, AP003122.6, TRIM77, AP003122.4, AP003122.5, UBTFL2, AP003122.2, AP003122.3, AP003122.1, TRIM64DP, AP004833.2, AP004833.3, TRIM49, AP004833.1, TRIM53BP, TRIM51BP, AP005435.1, TRIM64B, AP005435.4, AP005435.2, AP005435.3, MTND1P35, TRIM49D1, TRIM49D2, AP004607.3, AP004607.9, AP004607.8, AP004607.1, TRIM64, AP004607.7, TRIM51EP, TRIM53AP, AP004607.6, TRIM49C, AP004607.2, AP004607.4, TRIM64EP.
- chr11:100,641,975–104,609,498, 66 genes, copy number 5 (broad region; genes not listed).
- chr20:44,885,702–51,562,831, 197 genes, copy number 6–7 (broad region; genes not listed).
- chr20:51,782,331–54,269,542, 37 genes, copy number 5: SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, PFDN4, AL133335.1.

Autosomal genes at a single copy (total copy number 1): 9,734. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
